Somatic mutation profile of tumor specimen TCGA-FR-A7U8-06A (aliquot TCGA-FR-A7U8-06A-21D-A34U-08) from TCGA case TCGA-FR-A7U8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.2 years (18,698 days).
Specimen TCGA-FR-A7U8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a127e8-44b9-457b-b725-640f2bd53943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A7U8-10A (Blood Derived Normal), aliquot TCGA-FR-A7U8-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80cfe927-35c3-4619-b7eb-4d98a6ecdb52

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLPH | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 49/116 reads (42%) | catalogued as rs140470472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 143/208 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARMCX3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1556038386, COSV100362344; called by muse, mutect2, varscan2
- CDH2 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV99296234, COSV99298880; called by muse, mutect2, varscan2
- DAXX | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773142629, COSV56466378; called by muse, mutect2, varscan2
- DOCK5 | c.3886C>T p.L1296F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99378244; called by muse, mutect2, varscan2
- DRC7 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.857); catalogued as rs532170531, COSV100395375; called by muse, mutect2, varscan2
- FH | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.07); catalogued as COSV100845103; called by muse, mutect2, varscan2
- IGHMBP2 | c.2857G>A p.G953S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775514650, COSV99662014, COSV99662669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT31 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.059); catalogued as COSV52438553, COSV99290256; called by muse, mutect2, varscan2
- MAGEB6B | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1373548278; called by muse, mutect2, varscan2
- MAP2K4 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100796572; called by muse, mutect2, varscan2
- MECOM | c.1276G>C p.E426Q (on ENST00000468789 / NM_001105078.4; = p.E614Q on NM_004991.4) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV99245732; called by muse, mutect2, varscan2
- PCDHGB6 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1389452276, COSV99548804; called by muse, mutect2, varscan2
- PLCD4 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs940357845, COSV101346978; called by muse, mutect2, varscan2
- RGS22 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs866372358, COSV62665536; called by muse, mutect2, varscan2
- RP1L1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs780471247, COSV101223761; called by muse, mutect2, varscan2
- SETD5 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100201223; called by muse, mutect2, varscan2
- SP100 | c.2548-1G>C p.X850_splice | Splice Site (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100414540; called by muse, mutect2, varscan2
- SP100 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100414541; called by muse, mutect2, varscan2
- TRIO | c.5126G>A p.G1709D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711105; called by muse, mutect2, varscan2
- TTC30B | c.1423T>A p.Y475N | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV68809220; called by muse, mutect2, varscan2
- TTC7B | c.2365G>C p.D789H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100128725; called by muse, mutect2, varscan2
- WDR7 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746056029, COSV99590650; called by muse, mutect2, varscan2
- ETS1 | c.743dup p.Q249Pfs*5 | Frame Shift Ins (INS) | VAF 16/29 reads (55%) | called by mutect2, pindel, varscan2
- MFSD14B | c.284dup p.L95Ffs*11 | Frame Shift Ins (INS) | VAF 54/137 reads (39%) | called by mutect2, pindel, varscan2
- ACSM2B | c.804C>T p.N268= | Silent (SNP) | VAF 90/189 reads (48%) | catalogued as rs776475192, COSV100313247; called by muse, mutect2, varscan2
- CARMIL2 | c.180G>A p.P60= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs771595439, COSV58031208; called by muse, mutect2, varscan2
- FAT4 | c.10290C>G p.A3430= | Silent (SNP) | VAF 51/66 reads (77%) | catalogued as COSV100630492; called by muse, mutect2, varscan2
- FMN2 | c.3594G>A p.P1198= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs200759129, COSV100143848; called by muse, varscan2
- LTBP1 | c.3066C>T p.C1022= (on ENST00000404816 / NM_206943.4; = p.C696= on NM_000627.4) | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs763312851, COSV100618042; called by muse, mutect2, varscan2
- OR51B4 | c.231C>A p.P77= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100972193; called by muse, mutect2, varscan2
- PCDHB7 | c.1620G>A p.A540= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV50754071; called by muse, mutect2
- PSG2 | c.696C>T p.T232= | Silent (SNP) | VAF 140/358 reads (39%) | catalogued as rs1487378538, COSV100283750; called by muse, mutect2, varscan2
- QPRT | c.42C>T p.T14= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs745491280, COSV99569089; called by muse, mutect2, varscan2
- TFE3 | c.609G>A p.L203= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as COSV100252913; called by muse, mutect2, varscan2
- WBP11 | c.1608C>T p.A536= | Silent (SNP) | VAF 151/350 reads (43%) | catalogued as rs200349132, COSV99660949; called by muse, mutect2, varscan2
- SKP2 | c.1062-1591T>A | Intron (SNP) | VAF 73/149 reads (49%) | called by muse, mutect2, varscan2
